Somatic mutation profile of tumor specimen MMRF_1285_3_BM_CD138pos (aliquot MMRF_1285_3_BM_CD138pos_T1_KHS5U_L11591) from MMRF case MMRF_1285, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 75.3 years (27,512 days).
Specimen MMRF_1285_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bffe8f51-bc0c-4fc0-af8a-2f066ea27a54.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1285_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1285_1_PB_Whole_C1_KHS5U_L15100; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fa72accc-879a-4c64-9ac4-de5ae569432d

The open-access MAF lists 225 somatic variants for this specimen: 88 protein-altering or splice-affecting, 25 silent, 112 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, 3'UTR 66, Silent 25, Intron 23, 5'UTR 8, 5'Flank 6, 3'Flank 5, RNA 4, Splice Site 3, Splice Region 3, Nonsense Mutation 3, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 53/125 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- AKAP13 | c.7202A>T p.H2401L (on ENST00000394518 / NM_007200.5; = p.H2405L on NM_006738.6) | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV100774606; called by muse, mutect2, varscan2
- C1orf94 | c.1324G>A p.V442I (on ENST00000488417 / NM_001134734.2; = p.V252I on NM_032884.5) | Missense Mutation (SNP) | VAF 91/179 reads (51%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as rs1159086768; called by muse, mutect2, varscan2
- CEP162 | c.2747C>T p.A916V | Missense Mutation (SNP) | VAF 61/168 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as rs757345241; called by muse, mutect2, varscan2
- CNNM1 | c.1804C>T p.R602W | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs761658293, COSV63202446; called by muse, mutect2, varscan2
- CYP2B6 | c.1195C>A p.P399T | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as rs1209959748; called by muse, mutect2, varscan2
- DCAF12L1 | c.879C>A p.S293R | Missense Mutation (SNP) | VAF 59/63 reads (94%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.594); catalogued as COSV64421863, COSV64422822; called by muse, mutect2, varscan2
- DNAI3 | c.1617G>T p.K539N | Missense Mutation (SNP) | VAF 109/236 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.81); catalogued as COSV99641974; called by muse, mutect2, varscan2
- DUOX2 | c.-14-5C>T | Splice Region (SNP) | VAF 20/228 reads (9%) | catalogued as rs201463794; called by muse, mutect2
- ECPAS | c.104C>G p.P35R | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs750517890, COSV99398126; called by muse, mutect2, varscan2
- FCGBP | c.4354G>A p.E1452K | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0.32); catalogued as rs782466151; called by muse, mutect2, varscan2
- GPATCH2L | c.926G>A p.R309H | Missense Mutation (SNP) | VAF 48/103 reads (47%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.996); catalogued as rs781733578; called by muse, mutect2, varscan2
- GPR4 | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 55/176 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs1469399830, COSV59916303, COSV59916377; called by muse, mutect2, varscan2
- GZF1 | c.226A>G p.N76D | Missense Mutation (SNP) | VAF 93/212 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.239); catalogued as COSV100582676; called by muse, mutect2, varscan2
- LAMB3 | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs762942741, COSV61920286; called by muse, mutect2, varscan2
- LKAAEAR1 | c.431G>T p.R144L | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1319141240; called by muse, mutect2, varscan2
- LRP1B | c.6007G>C p.V2003L | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV67274279; called by muse, mutect2, varscan2
- MYH10 | c.2545C>T p.R849C | Missense Mutation (SNP) | VAF 68/171 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs777205800, COSV52603274; called by muse, mutect2, varscan2
- MYO7A | c.836A>T p.N279I | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.181); catalogued as COSV101289129; called by muse, mutect2, varscan2
- NAALAD2 | c.523T>G p.F175V | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752922518; called by muse, mutect2, varscan2
- NFATC2IP | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as rs779163433, COSV100297630; called by muse, mutect2, varscan2
- OAS1 | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT tolerated (0.54); PolyPhen benign (0.047); catalogued as COSV52535124; called by muse, mutect2, varscan2
- PCSK9 | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs865914100, COSV100134964; called by muse, mutect2
- PDGFRA | c.1021G>C p.A341P | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV57269361; called by muse, mutect2
- PLCH2 | c.4175A>C p.D1392A | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.036); catalogued as rs1169642720; called by muse, mutect2, varscan2
- PLCZ1 | c.972_973del p.V326Kfs*25 | Frame Shift Del (DEL) | VAF 63/164 reads (38%) | catalogued as rs777169092; called by mutect2, pindel, varscan2
- PLPPR1 | c.520C>G p.Q174E | Missense Mutation (SNP) | VAF 65/191 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.672); catalogued as COSV66459132; called by muse, mutect2, varscan2
- RBSN | c.248A>G p.Y83C | Missense Mutation (SNP) | VAF 65/136 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as rs1452059614; called by muse, mutect2, varscan2
- RFX2 | c.2156C>A p.S719Y | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.248); catalogued as COSV57945944; called by muse, mutect2, varscan2
- RYR3 | c.9442G>T p.G3148C (on ENST00000389232; = p.G3149C on NM_001036.6) | Missense Mutation (SNP) | VAF 122/350 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759037751, COSV66801379, COSV66803450; called by muse, mutect2, varscan2
- SLC25A5 | c.890A>G p.Y297C | Missense Mutation (SNP) | VAF 22/27 reads (81%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV58625899; called by muse, mutect2, varscan2
- SMIM7 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 76/230 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as rs779327008, COSV62417775; called by muse, mutect2, varscan2
- SYNE1 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 59/64 reads (92%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs767703161; called by muse, mutect2, varscan2
- TRMT10C | c.284G>A p.R95K | Missense Mutation (SNP) | VAF 101/222 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.041); catalogued as COSV99998290; called by muse, mutect2, varscan2
- USH2A | c.4627+2T>C p.X1543_splice (on ENST00000307340 / NM_206933.4; = p.G1543= on NM_007123.6) | Splice Site (SNP) | VAF 64/101 reads (63%) | catalogued as CS136560; called by muse, mutect2, varscan2
- ZNF292 | c.2185C>T p.R729W | Missense Mutation (SNP) | VAF 60/129 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60546480; called by muse, mutect2, varscan2
- ADCY5 | c.1706G>A p.R569Q | Missense Mutation (SNP) | VAF 77/195 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ARRB1 | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- ASPSCR1 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- ATP2B2 | c.184A>T p.T62S | Missense Mutation (SNP) | VAF 52/118 reads (44%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- AUTS2 | c.410C>T p.S137L | Missense Mutation (SNP) | VAF 41/148 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- BPNT1 | c.475-1G>A p.X159_splice | Splice Site (SNP) | VAF 13/45 reads (29%) | called by muse, mutect2, varscan2
- C16orf71 | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- C1GALT1 | c.875A>C p.Y292S | Missense Mutation (SNP) | VAF 80/272 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- C3orf56 | c.353C>G p.P118R | Missense Mutation (SNP) | VAF 85/241 reads (35%) | SIFT tolerated (0.94); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CCNE2 | c.388T>C p.F130L | Missense Mutation (SNP) | VAF 126/264 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CDH20 | c.2381C>T p.S794L | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CFAP52 | c.328C>T p.H110Y | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CHRNA6 | c.656A>G p.K219R | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.919); called by muse, mutect2
- CLIP3 | c.54_65del p.E20_E23del | In Frame Del (DEL) | VAF 20/96 reads (21%) | called by mutect2, varscan2
- COX10 | c.1052G>C p.G351A | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- COX8A | c.119T>C p.L40S | Missense Mutation (SNP) | VAF 64/167 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- DOP1B | c.3333G>T p.E1111D | Missense Mutation (SNP) | VAF 93/105 reads (89%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ELAPOR1 | c.320C>T p.S107L | Missense Mutation (SNP) | VAF 80/197 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- ELN | c.1607C>A p.A536D | Missense Mutation (SNP) | VAF 102/269 reads (38%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ESX1 | c.445T>C p.F149L | Missense Mutation (SNP) | VAF 44/47 reads (94%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FAT3 | c.5353A>T p.N1785Y | Missense Mutation (SNP) | VAF 85/190 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRXCR1 | c.482A>C p.K161T | Missense Mutation (SNP) | VAF 105/225 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GTF2IRD2B | c.1285C>T p.Q429* | Nonsense Mutation (SNP) | VAF 49/281 reads (17%) | called by muse, mutect2, varscan2
- HLA-DQB1 | c.661+5G>A | Splice Region (SNP) | VAF 54/180 reads (30%) | called by muse, mutect2, varscan2
- IVL | c.38C>A p.P13H | Missense Mutation (SNP) | VAF 196/604 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- JAKMIP2 | c.1175T>C p.L392P | Missense Mutation (SNP) | VAF 56/188 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KIAA2012 | c.249G>T p.W83C | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- LRCH4 | c.949-4del | Splice Region (DEL) | VAF 37/154 reads (24%) | called by mutect2, pindel*, varscan2
- MAFA | c.676C>G p.R226G | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- MBD4 | c.1064C>A p.S355Y | Missense Mutation (SNP) | VAF 75/145 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- MOCOS | c.526G>T p.D176Y | Missense Mutation (SNP) | VAF 87/163 reads (53%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.961); called by muse, mutect2
- NUAK2 | c.1220C>T p.P407L | Missense Mutation (SNP) | VAF 10/223 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); called by muse, mutect2
- OR4E2 | c.503A>T p.Y168F | Missense Mutation (SNP) | VAF 10/272 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.403); called by muse, mutect2
- OR5P2 | c.818T>C p.L273S | Missense Mutation (SNP) | VAF 56/114 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- P3H2 | c.1777T>A p.C593S | Missense Mutation (SNP) | VAF 61/211 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHGB4 | c.1714C>G p.L572V | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- PEX12 | c.214C>T p.Q72* | Nonsense Mutation (SNP) | VAF 16/143 reads (11%) | called by muse, mutect2, varscan2
- POTEA | c.311A>C p.H104P | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- PPFIBP1 | c.475C>A p.L159I | Missense Mutation (SNP) | VAF 68/134 reads (51%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- RELA | c.905G>C p.R302P | Missense Mutation (SNP) | VAF 53/114 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- RIN2 | c.1252G>C p.E418Q (on ENST00000255006 / NM_001242581.1; = p.E369Q on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/156 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RPRD2 | c.541A>C p.K181Q | Missense Mutation (SNP) | VAF 43/129 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.618); called by muse, mutect2, varscan2
- SERINC2 | c.577G>A p.A193T (on ENST00000373709 / NM_178865.5; = p.A197T on NM_018565.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TAP1 | c.778+1G>C p.X260_splice | Splice Site (SNP) | VAF 52/83 reads (63%) | called by muse, mutect2, varscan2
- TRIM9 | c.1714A>C p.T572P | Missense Mutation (SNP) | VAF 65/147 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- VN1R4 | c.751C>T p.L251F | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- WIZ | c.3802C>T p.P1268S | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ZFPM2 | c.2269C>T p.Q757* | Nonsense Mutation (SNP) | VAF 63/152 reads (41%) | called by muse, mutect2, varscan2
- ZNF443 | c.925del p.Y309Ifs*48 | Frame Shift Del (DEL) | VAF 127/522 reads (24%) | called by pindel, varscan2
- ZNF470 | c.323A>G p.N108S | Missense Mutation (SNP) | VAF 89/142 reads (63%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF568 | c.1080A>C p.K360N | Missense Mutation (SNP) | VAF 54/248 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ZNF883 | c.527C>A p.S176Y | Missense Mutation (SNP) | VAF 64/225 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- AKAP6 | c.945C>T p.V315= | Silent (SNP) | VAF 49/105 reads (47%) | catalogued as rs745590868; called by muse, mutect2, varscan2
- ALOX12B | c.981G>A p.V327= | Silent (SNP) | VAF 32/77 reads (42%) | called by muse, mutect2, varscan2
- ALPI | c.1002C>T p.I334= | Silent (SNP) | VAF 74/174 reads (43%) | catalogued as rs375112950; called by muse, mutect2, varscan2
- ANKRD24 | c.2889G>A p.A963= | Silent (SNP) | VAF 40/112 reads (36%) | catalogued as rs781160528; called by muse, mutect2, varscan2
- ARHGEF17 | c.1212A>T p.L404= | Silent (SNP) | VAF 112/241 reads (46%) | called by muse, mutect2, varscan2
- C12orf40 | c.894T>C p.S298= | Silent (SNP) | VAF 44/92 reads (48%) | called by muse, mutect2, varscan2
- CAMSAP3 | c.1458C>T p.H486= | Silent (SNP) | VAF 118/389 reads (30%) | called by muse, mutect2, varscan2
- CPA2 | c.594T>G p.S198= | Silent (SNP) | VAF 36/136 reads (26%) | called by muse, mutect2, varscan2
- DLG2 | c.384T>C p.F128= | Silent (SNP) | VAF 22/41 reads (54%) | called by muse, mutect2, varscan2
- FANCI | c.3498G>A p.L1166= (on ENST00000310775 / NM_001376911.1; = p.L1106= on NM_018193.3) | Silent (SNP) | VAF 48/101 reads (48%) | called by muse, mutect2, varscan2
- FAP | c.1125A>G p.K375= | Silent (SNP) | VAF 20/40 reads (50%) | catalogued as rs1363568858; called by muse, mutect2, varscan2
- GAL3ST1 | c.649C>T p.L217= | Silent (SNP) | VAF 17/260 reads (7%) | catalogued as rs1472838461; called by muse, mutect2
- HEATR1 | c.750G>A p.L250= | Silent (SNP) | VAF 23/67 reads (34%) | called by muse, mutect2, varscan2
- INPP5D | c.2058G>A p.V686= (on ENST00000445964 / NM_001017915.3; = p.V685= on NM_005541.5) | Silent (SNP) | VAF 78/133 reads (59%) | catalogued as rs1266688100, COSV100856614; called by muse, mutect2, varscan2
- JPT1 | c.243A>C p.G81= | Silent (SNP) | VAF 21/71 reads (30%) | called by muse, mutect2, varscan2
- KRT73 | c.1086G>A p.S362= | Silent (SNP) | VAF 41/96 reads (43%) | catalogued as rs759355959, COSV59840034; called by muse, mutect2, varscan2
- MMP25 | c.198G>A p.Q66= | Silent (SNP) | VAF 33/52 reads (63%) | called by muse, mutect2, varscan2
- MTFR1 | c.558C>T p.H186= | Silent (SNP) | VAF 37/114 reads (32%) | called by muse, mutect2, varscan2
- OR2J3 | c.204C>T p.N68= | Silent (SNP) | VAF 151/399 reads (38%) | catalogued as rs201161327, COSV101013642; called by muse, mutect2, varscan2
- PAPPA2 | c.1941C>A p.P647= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV62789639; called by muse, mutect2, varscan2
- STAR | c.18C>T p.F6= | Silent (SNP) | VAF 62/153 reads (41%) | catalogued as rs1012931648; called by muse, mutect2, varscan2
- STKLD1 | c.232C>T p.L78= | Silent (SNP) | VAF 80/285 reads (28%) | called by muse, mutect2, varscan2
- ZBTB40 | c.2802T>C p.N934= | Silent (SNP) | VAF 61/146 reads (42%) | catalogued as rs1461864693; called by muse, mutect2, varscan2
- ZFHX4 | c.8089C>A p.R2697= | Silent (SNP) | VAF 11/219 reads (5%) | called by muse, mutect2
- ZNF169 | c.1314T>C p.G438= | Silent (SNP) | VAF 81/277 reads (29%) | catalogued as rs1176664150; called by muse, mutect2, varscan2
- ABRAXAS1 | c.87+33G>C | Intron (SNP) | VAF 16/30 reads (53%) | called by muse, mutect2
- AC006288.1 | n.134G>A | RNA (SNP) | VAF 52/152 reads (34%) | called by muse, mutect2, varscan2
- ACADSB | c.*3163A>T | 3'UTR (SNP) | VAF 4/94 reads (4%) | called by muse, mutect2
- ACTR1A | c.*414G>A | 3'UTR (SNP) | VAF 8/196 reads (4%) | called by muse, mutect2
- ACTR1A | c.*413G>T | 3'UTR (SNP) | VAF 8/194 reads (4%) | called by muse, mutect2
- ADAMTS2 | c.*246T>C | 3'UTR (SNP) | VAF 64/187 reads (34%) | called by muse, mutect2, varscan2
- ADCYAP1 | c.*426A>G | 3'UTR (SNP) | VAF 17/40 reads (43%) | called by muse, mutect2, varscan2
- ADGRG5 | c.*197C>A | 3'UTR (SNP) | VAF 26/59 reads (44%) | called by muse, mutect2, varscan2
- ARF3 | c.*2396A>G | 3'UTR (SNP) | VAF 70/130 reads (54%) | catalogued as rs1046231981; called by muse, mutect2, varscan2
- ASGR1 | c.70+104G>T | Intron (SNP) | VAF 65/163 reads (40%) | called by muse, mutect2, varscan2
- ATP13A4 | c.1674+204A>T | Intron (SNP) | VAF 63/183 reads (34%) | called by muse, mutect2, varscan2
- B3GAT2 | c.*2207C>T | 3'UTR (SNP) | VAF 43/113 reads (38%) | called by muse, mutect2, varscan2
- BCKDHB | c.*100C>G | 3'UTR (SNP) | VAF 18/338 reads (5%) | catalogued as rs932586340; called by muse, mutect2
- C1QTNF3 | c.482-78G>A | Intron (SNP) | VAF 9/40 reads (23%) | called by muse, mutect2
- C1orf109 | c.456-18T>C | Intron (SNP) | VAF 48/107 reads (45%) | called by muse, mutect2, varscan2
- CACNA1E | c.*6783A>G | 3'UTR (SNP) | VAF 30/79 reads (38%) | called by muse, mutect2, varscan2
- CACNA2D1 | chr7:81947026 A>G | 3'Flank (SNP) | VAF 70/126 reads (56%) | called by muse, mutect2, varscan2
- CAMSAP1 | c.*2565C>T | 3'UTR (SNP) | VAF 57/148 reads (39%) | called by muse, mutect2, varscan2
- CASC3 | c.*881A>C | 3'UTR (SNP) | VAF 46/122 reads (38%) | called by muse, mutect2, varscan2
- CASP14 | c.404-21C>A | Intron (SNP) | VAF 51/146 reads (35%) | called by muse, mutect2, varscan2
- CCDC38 | c.38-679del | Intron (DEL) | VAF 13/128 reads (10%) | called by mutect2, pindel, varscan2
- CCL14 | c.*49G>C | 3'UTR (SNP) | VAF 40/106 reads (38%) | called by muse, mutect2, varscan2
- CCL17 | c.*32C>T | 3'UTR (SNP) | VAF 38/70 reads (54%) | called by muse, mutect2, varscan2
- CCNY | c.*1448G>T | 3'UTR (SNP) | VAF 48/91 reads (53%) | called by muse, mutect2, varscan2
- CD300LD | chr17:74592467 G>T | 5'Flank (SNP) | VAF 56/130 reads (43%) | catalogued as rs143676086; called by muse, mutect2, varscan2
- CDH8 | c.*1379C>T | 3'UTR (SNP) | VAF 39/80 reads (49%) | called by muse, mutect2, varscan2
- CFAP43 | c.1442+521C>A | Intron (SNP) | VAF 27/73 reads (37%) | called by muse, mutect2, varscan2
- CHMP1A | c.*189G>C | 3'UTR (SNP) | VAF 114/292 reads (39%) | called by muse, mutect2, varscan2
- CKMT2 | c.*78C>T | 3'UTR (SNP) | VAF 76/229 reads (33%) | called by muse, mutect2, varscan2
- CLK3 | c.-28T>G | 5'UTR (SNP) | VAF 10/26 reads (38%) | called by muse, mutect2, varscan2
- COPB1 | c.1737+102A>T | Intron (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2, varscan2
- CUX1 | c.*8828A>C | 3'UTR (SNP) | VAF 14/38 reads (37%) | called by muse, mutect2, varscan2
- DCLK3 | c.-155C>T | 5'UTR (SNP) | VAF 18/37 reads (49%) | called by muse, mutect2, varscan2
- DNAJC24 | c.*2011T>G | 3'UTR (SNP) | VAF 48/53 reads (91%) | called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.*1206C>A | 3'UTR (SNP) | VAF 33/112 reads (29%) | called by muse, mutect2, varscan2
- EFNA5 | c.*3022G>T | 3'UTR (SNP) | VAF 15/59 reads (25%) | called by muse, mutect2, varscan2
- EIF3F | chr11:7998683 A>T | 3'Flank (SNP) | VAF 25/56 reads (45%) | called by muse, mutect2, varscan2
- ENKUR | c.*1540G>C | 3'UTR (SNP) | VAF 52/110 reads (47%) | called by muse, mutect2, varscan2
- ESAM | c.451+61C>A | Intron (SNP) | VAF 32/76 reads (42%) | called by muse, mutect2, varscan2
- FMN1 | c.*4926T>C | 3'UTR (SNP) | VAF 47/77 reads (61%) | called by muse, mutect2, varscan2
- GABRA4 | c.*7834T>A | 3'UTR (SNP) | VAF 28/65 reads (43%) | called by muse, mutect2, varscan2
- GATAD2B | c.*4781G>A | 3'UTR (SNP) | VAF 60/163 reads (37%) | called by muse, mutect2, varscan2
- GLS2 | chr12:56488217 G>T | 5'Flank (SNP) | VAF 14/40 reads (35%) | called by muse, mutect2
- GMEB2 | c.*1380G>T | 3'UTR (SNP) | VAF 11/296 reads (4%) | called by muse, mutect2
- GRM7 | c.519+94662A>T | Intron (SNP) | VAF 106/227 reads (47%) | called by muse, mutect2, varscan2
- GSN-AS1 | n.3970T>A | RNA (SNP) | VAF 18/560 reads (3%) | called by muse, mutect2
- H2AC12 | c.*36T>C | 3'UTR (SNP) | VAF 111/401 reads (28%) | called by muse, mutect2, varscan2
- IRX6 | c.-412T>G | 5'UTR (SNP) | VAF 45/105 reads (43%) | catalogued as rs1370432289; called by muse, mutect2, varscan2
- KIAA1755 | c.*1518G>A | 3'UTR (SNP) | VAF 7/68 reads (10%) | called by muse, mutect2
- KIAA2012 | c.1908+58T>C | Intron (SNP) | VAF 82/194 reads (42%) | called by muse, mutect2, varscan2
- KPNA1 | c.*4911C>T | 3'UTR (SNP) | VAF 22/57 reads (39%) | called by muse, mutect2, varscan2
- L1TD1 | c.-24T>G | 5'UTR (SNP) | VAF 130/261 reads (50%) | called by muse, mutect2, varscan2
- L1TD1 | c.-23C>A | 5'UTR (SNP) | VAF 130/263 reads (49%) | called by muse, mutect2, varscan2
- LMAN2L | c.*1254G>C | 3'UTR (SNP) | VAF 7/68 reads (10%) | called by muse, mutect2
- LRRC10 | c.*76G>T | 3'UTR (SNP) | VAF 48/94 reads (51%) | called by muse, mutect2, varscan2
- MAEL | c.225+105del | Intron (DEL) | VAF 16/67 reads (24%) | called by mutect2, pindel, varscan2
- MED19 | c.572-30C>T | Intron (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
- MIEF1 | c.*2383A>G | 3'UTR (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
- MIR411 | n.36G>A | RNA (SNP) | VAF 28/49 reads (57%) | called by muse, mutect2, varscan2
- MTARC2 | c.*335A>C | 3'UTR (SNP) | VAF 16/65 reads (25%) | called by muse, mutect2, varscan2
- MTURN | c.*3757del | 3'UTR (DEL) | VAF 17/93 reads (18%) | called by mutect2, pindel, varscan2
- MYEF2 | c.*2021C>T | 3'UTR (SNP) | VAF 28/114 reads (25%) | catalogued as rs912397620; called by muse, mutect2, varscan2
- MYF5 | c.*237G>A | 3'UTR (SNP) | VAF 20/33 reads (61%) | called by muse, mutect2, varscan2
- MYO5C | c.*263G>C | 3'UTR (SNP) | VAF 19/69 reads (28%) | called by muse, mutect2, varscan2
- NAB1 | c.*1475A>C | 3'UTR (SNP) | VAF 43/83 reads (52%) | called by muse, mutect2, varscan2
- NAP1L4 | c.607-52C>T | Intron (SNP) | VAF 13/27 reads (48%) | called by muse, mutect2, varscan2
- NDUFA8 | c.-22C>T | 5'UTR (SNP) | VAF 109/309 reads (35%) | catalogued as rs1442518315; called by muse, mutect2, varscan2
- NDUFB2 | chr7:140696663 C>T | 5'Flank (SNP) | VAF 4/12 reads (33%) | called by muse, varscan2
- NEDD4 | c.*2107A>T | 3'UTR (SNP) | VAF 26/95 reads (27%) | called by mutect2, varscan2
- NHLH2 | chr1:115841196 G>C | 5'Flank (SNP) | VAF 18/49 reads (37%) | catalogued as COSV57201698; called by muse, mutect2, varscan2
- NPR3 | c.*1687C>A | 3'UTR (SNP) | VAF 38/129 reads (29%) | called by muse, mutect2, varscan2
- NTRK3 | chr15:87871797 A>G | 3'Flank (SNP) | VAF 56/108 reads (52%) | catalogued as rs990860431; called by muse, mutect2, varscan2
- NYAP2 | c.*1606C>A | 3'UTR (SNP) | VAF 44/110 reads (40%) | called by muse, mutect2, varscan2
- OR2A12 | chr7:144096177 T>A | 3'Flank (SNP) | VAF 19/54 reads (35%) | called by muse, mutect2, varscan2
- OSBPL2 | chr20:62232976 C>A | 5'Flank (SNP) | VAF 32/113 reads (28%) | called by muse, mutect2, varscan2
- PAPPA2 | c.2431+557C>A | Intron (SNP) | VAF 29/109 reads (27%) | called by muse, mutect2, varscan2
- PARVA | c.*2469_*2471del | 3'UTR (DEL) | VAF 12/49 reads (24%) | called by pindel, varscan2
- PGAP1 | c.1952+156G>C | Intron (SNP) | VAF 37/80 reads (46%) | called by muse, mutect2, varscan2
- PHOSPHO1 | c.*499G>A | 3'UTR (SNP) | VAF 57/140 reads (41%) | called by muse, mutect2, varscan2
- PHYHIPL | c.*411G>T | 3'UTR (SNP) | VAF 43/106 reads (41%) | called by muse, mutect2, varscan2
- PPARGC1A | c.234+299A>C | Intron (SNP) | VAF 37/67 reads (55%) | called by muse, mutect2
- PTHLH | c.-23+152T>C | Intron (SNP) | VAF 73/171 reads (43%) | called by muse, mutect2, varscan2
- RAB30 | chr11:82978507 del G | 3'Flank (DEL) | VAF 6/37 reads (16%) | catalogued as rs1416417208; called by pindel, varscan2
- RALGPS1 | c.*936C>T | 3'UTR (SNP) | VAF 125/331 reads (38%) | called by muse, mutect2, varscan2
- RBL1 | c.*1657G>A | 3'UTR (SNP) | VAF 58/133 reads (44%) | called by muse, mutect2, varscan2
- RBM44 | c.14+75A>C | Intron (SNP) | VAF 5/69 reads (7%) | called by muse, mutect2
- RIF1 | c.*1998A>C | 3'UTR (SNP) | VAF 31/72 reads (43%) | called by muse, mutect2, varscan2
- RNF169 | c.*641G>T | 3'UTR (SNP) | VAF 91/99 reads (92%) | called by muse, mutect2, varscan2
- ROCK2 | c.*79A>G | 3'UTR (SNP) | VAF 153/358 reads (43%) | called by muse, mutect2, varscan2
- S1PR3 | c.*2195G>T | 3'UTR (SNP) | VAF 33/112 reads (29%) | called by muse, mutect2
- SH3PXD2B | c.*1638G>A | 3'UTR (SNP) | VAF 4/96 reads (4%) | catalogued as rs1307280895; called by muse, mutect2
- SLC1A2 | c.-218G>C | 5'UTR (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2, varscan2
- SLC7A8 | c.*174C>A | 3'UTR (SNP) | VAF 49/107 reads (46%) | called by muse, mutect2, varscan2
- SNX17 | c.*304C>T | 3'UTR (SNP) | VAF 53/119 reads (45%) | catalogued as rs1558309169; called by muse, mutect2, varscan2
- SRRM4 | c.*1185G>T | 3'UTR (SNP) | VAF 72/164 reads (44%) | called by muse, mutect2, varscan2
- STK17A | c.*1035T>C | 3'UTR (SNP) | VAF 32/81 reads (40%) | called by muse, mutect2, varscan2
- STRIP2 | c.1476+45T>A | Intron (SNP) | VAF 40/111 reads (36%) | called by muse, mutect2, varscan2
- SUPT4H1 | c.*35C>G | 3'UTR (SNP) | VAF 14/30 reads (47%) | called by muse, mutect2, varscan2
- TBRG4 | chr7:45111719 T>C | 5'Flank (SNP) | VAF 22/84 reads (26%) | called by muse, mutect2, varscan2
- TCTN1 | c.473-737C>T | Intron (SNP) | VAF 11/85 reads (13%) | called by muse, mutect2, varscan2
- TEAD1 | c.*5494A>G | 3'UTR (SNP) | VAF 30/72 reads (42%) | called by muse, mutect2, varscan2
- TMEM185A | c.*1153C>T | 3'UTR (SNP) | VAF 86/329 reads (26%) | called by muse, mutect2, varscan2
- TNRC6B | c.*12381G>C | 3'UTR (SNP) | VAF 42/106 reads (40%) | called by muse, mutect2, varscan2
- TRDN | c.*1905G>A | 3'UTR (SNP) | VAF 14/15 reads (93%) | called by muse, mutect2, varscan2
- TRIM39 | c.*251G>T | 3'UTR (SNP) | VAF 8/118 reads (7%) | called by muse, mutect2
- TTN | c.10360+4337A>C | Intron (SNP) | VAF 42/84 reads (50%) | called by muse, mutect2, varscan2
- TUBA1B | c.-73T>C | 5'UTR (SNP) | VAF 44/96 reads (46%) | called by muse, mutect2, varscan2
- UGGT1 | c.*1361C>T | 3'UTR (SNP) | VAF 41/78 reads (53%) | called by muse, mutect2, varscan2
- VWC2L | c.*1097G>A | 3'UTR (SNP) | VAF 20/47 reads (43%) | called by muse, mutect2, varscan2
- ZDHHC17 | c.*2042G>C | 3'UTR (SNP) | VAF 43/88 reads (49%) | called by muse, mutect2, varscan2
- ZNF547 | c.*340T>C | 3'UTR (SNP) | VAF 38/120 reads (32%) | called by muse, mutect2, varscan2
- ZNF725P | n.1106A>C | RNA (SNP) | VAF 62/201 reads (31%) | called by muse, mutect2, varscan2
